Somatic mutation profile of tumor specimen MP2PRT-PAWAKH-TMP1-A (aliquot MP2PRT-PAWAKH-TMP1-A-1-0-D-A80M-36) from MP2PRT case MP2PRT-PAWAKH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,413 days).
Specimen MP2PRT-PAWAKH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ffeb9c6-8170-4ad0-a2a6-33a4c72dd2a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAKH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAKH-NB1-A-1-0-D-A80M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/358f77c5-59c9-40a4-803c-e031916e44b3

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH4 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 135/320 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs778555934, COSV64644256; called by muse, mutect2, varscan2
- ZNF385C | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 209/774 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs782185108; called by muse, mutect2, varscan2
- LATS2 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 181/411 reads (44%) | called by muse, mutect2, varscan2
- IGKV1D-8 | chr2:90221384 ins GGGAGGGCTCATACGAGGCT | 3'Flank (INS) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
